Gene-level copy-number profile of tumor specimen TCGA-55-8511-01A from TCGA case TCGA-55-8511, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 73.9 years (26,986 days).
Specimen TCGA-55-8511-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.e29c7621-be79-4953-8c3b-4af7ad1c654f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-55-8511-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e6fba258-56be-46c5-b8ff-447a8c2cbca2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 114; copy number 1: 18,043; copy number 2: 23,890; copy number 3: 13,749; copy number 4: 2,874; copy number 5: 600; copy number 6: 161; copy number 7: 255; copy number 8: 58; copy number 9: 50; copy number 11: 15; copy number 15: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-55-8511-01A-11D-2389-01): tumor purity 0.19, ploidy 3.18, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 953 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:161,118,086–164,357,364, 88 genes, copy number 5 (broad region; genes not listed).
- chr3:31,269,007–31,269,406, 1 gene, copy number 5: H3P11.
- chr6:167,607–12,585,404, 242 genes, copy number 7 (broad region; genes not listed).
- chr7:70,972–15,562,015, 259 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr8:13,536,029–13,536,135, 1 gene, copy number 6: RNA5SP255.
- chr8:46,028,804–47,960,178, 39 genes, copy number 6 (within-gene range 2–6): AC118650.1, HSPA8P13, ASNSP1, AC104576.1, ASNSP4, AC021451.1, TRIM60P15, AC021451.2, AC021451.3, LINC00293, MTND2P38, MTND1P7, RNU6-656P, MTCYBP20, MTND6P20, AC091163.3, AC091163.1, AC091163.2, MAPK6P4, RN7SKP32, AC120036.1, AC120036.5, RNU6-819P, RPL10AP2, NDUFA5P12, AC120036.3, AC120036.4, ATP6V1G1P2, AC120036.2, IGLV8OR8-1, SPIDR, AC024451.2, AC024451.4, AC024451.1, AC024451.3, RNU6-665P, CEBPD, PRKDC, Y_RNA.
- chr8:57,126,655–57,365,444, 7 genes, copy number 5: RNA5SP266, LINC01606, AC025674.1, AC025674.2, LINC00588, RNU6-596P, AC068075.1.
- chr8:76,162,119–80,595,703, 61 genes, copy number 7–15 (broad region; genes not listed).
- chr8:81,439,436–81,521,818, 1 gene, copy number 6 (within-gene range 3–6): AC018616.1.
- chr8:81,478,419–82,961,926, 21 genes, copy number 6 (within-gene range 4–6): FABP4, AC023644.1, FTH1P11, FABP12, IMPA1P1, NIPA2P4, RPS26P34, SLC10A5P1, IMPA1, SLC10A5, AC132219.2, ZFAND1, CHMP4C, AC132219.1, SNX16, HNRNPA1P36, LINC02235, AC060765.2, LINC02839, HNRNPA1P4, AC060765.1.
- chr8:107,160,354–108,787,594, 19 genes, copy number 5 (within-gene range 3–5): AP000428.2, HMGB1P46, AP000428.1, ANGPT1, AC091010.1, PGAM1P13, AC025508.1, RNA5SP275, RSPO2, NRBF2P4, AURKBP1, EIF3E, AC087620.1, RPS17P14, EMC2, AC022634.1, AC022634.2, TMEM74, TRMT10BP1.
- chr8:120,812,219–123,416,350, 43 genes, copy number 5: AC104958.2, AC068413.1, AC011626.1, RPL35AP19, HAS2, HAS2-AS1, LINC02855, AC037486.1, MRPS36P3, SMILR, LINC01151, AC108136.1, AC100872.1, AC100872.2, CDK5P1, AC016405.3, AC016405.2, ZHX2, AC016405.1, AC104316.2, AC104316.1, DERL1, TBC1D31, HMGB1P19, AC068228.3, FAM83A, U3, AC068228.1, AC068228.2, FAM83A-AS1, MIR4663, C8orf76, ZHX1-C8orf76, UBA52P5, ZHX1, RNU6-628P, AC018992.1, ATAD2, RNU6-875P, MIR548AA1, MIR548D1, DUTP2, IMPDH1P6.
- chr8:137,105,352–139,704,109, 15 genes, copy number 5: RNU6-144P, ZYXP1, AC105213.1, AC110053.1, AC046195.1, AC046195.2, AC079015.1, FAM135B, COL22A1, AC027541.1, AC100807.1, AC100807.2, AC087354.1, AC090093.1, KCNK9.
- chr8:141,055,290–141,968,841, 23 genes, copy number 8: AC100860.1, DENND3, AC040970.1, SLC45A4, AC011676.5, AC011676.1, AC011676.2, AC011676.3, AC011676.4, LINC01300, AC100803.3, GPR20, AC100803.2, PTP4A3, MROH5, AC100803.4, AC100803.1, HNRNPA1P38, AC138647.2, AC138647.1, AC025839.1, MIR1302-7, AC104417.1.
- chr14:20,090,130–20,641,691, 44 genes, copy number 9: RNA5SP380, OR4T1P, OR4K17, OR4N5, PSMB7P1, GTF2IP22, OR11G1P, OR11P1P, OR11G2, OR11H5P, OR11H6, OR11H7, OR11H4, TTC5, AL356019.2, AL356019.1, CCNB1IP1, AL355075.6, SNORA79B, SNORD126, AL355075.4, RPPH1, PARP2, AL355075.1, TEP1, RNA5SP382, KLHL33, AL355075.5, OSGEP, AL355075.2, APEX1, PIP4P1, PNP, AL355075.3, RNASE10, PTCD2P1, SETP1, RNASE9, AL163195.3, RNASE11, AL163195.2, RNASE12, AL163195.1, OR6S1.
- chr14:21,057,822–21,206,900, 11 genes, copy number 7: RNASE8, ARHGEF40, ZNF219, TMEM253, AL161668.1, CKAP2P1, RNU6-252P, OR5AU1, SMARCE1P3, AL157687.1, LINC00641.
- chr14:29,210,986–29,500,460, 4 genes, copy number 9: AL133166.1, AL158058.1, AL158058.2, RNU11-5P.
- chr14:29,652,809–29,812,018, 2 genes, copy number 9: AL356756.1, RNU6-1234P.
- chr14:35,534,164–38,987,383, 59 genes, copy number 6: INSM2, RALGAPA1, AL137818.1, QRSL1P3, AL162311.3, NUTF2P2, BRMS1L, AL162311.1, AL162311.2, AL133304.3, AL133304.1, ILF2P2, AL133304.2, LINC00609, PTCSC3, AL162511.1, RN7SKP21, MBIP, AL132857.1, DPPA3P2, RNU7-93P, SFTA3, SFTA3, NKX2-1, NKX2-1-AS1, PHKBP2, RPL29P3, NKX2-8, RN7SKP257, AL079303.1, PAX9, SLC25A21, AL162464.2, AL162464.1, MIR4503, AL079304.1, SLC25A21-AS1, RNU6-273P, MIPOL1, RNU6-886P, AL121790.2, AL121790.1, FOXA1, TTC6, AL136296.1, RNU6-1277P, LINC00517, AL359233.1, AL392023.2, AL392023.1, SSTR1, CLEC14A, AL355835.1, AL357094.1, KRT8P1, LINC00639, AL132994.1, AL132994.2, Y_RNA.
- chr14:40,954,693–41,298,734, 2 genes, copy number 6: LINC02315, AL391516.1.
- chr14:47,760,995–48,491,767, 11 genes, copy number 6: MIR548Y, LINC00648, AL121576.1, AL359212.1, AL512358.1, AL512358.2, AL358335.3, RNU6-297P, AL358335.2, AL358335.1, RPL18P1.

Autosomal genes at a single copy (total copy number 1): 15,949. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
